Somatic mutation profile of tumor specimen TARGET-40-PANGPE-01A (aliquot TARGET-40-PANGPE-01A-01D) from TARGET case TARGET-40-PANGPE, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 13.1 years (4,794 days).
Specimen TARGET-40-PANGPE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55b6c83a-e489-421b-a6bd-b40babecfc1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PANGPE-10A (Blood Derived Normal), aliquot TARGET-40-PANGPE-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47c6d03d-4158-4a47-93da-69eb62c051ac

The open-access MAF lists 32 somatic variants for this specimen: 19 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 10, Intron 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTG2 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 223/602 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.23); catalogued as rs1553394796, COSV61830035; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KDR | c.3197G>A p.R1066H | Missense Mutation (SNP) | VAF 143/362 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754208569, COSV55765338; called by muse, mutect2, varscan2
- PCDHGA3 | c.1513G>A p.V505I | Missense Mutation (SNP) | VAF 487/740 reads (66%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.044); catalogued as COSV53891908; called by muse, mutect2, varscan2
- PHGDH | c.1420G>A p.D474N | Missense Mutation (SNP) | VAF 411/1132 reads (36%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as rs749952154; called by muse, mutect2, varscan2
- PROX2 | c.1676G>A p.G559E (on ENST00000556489 / NM_001243007.1; = p.G332E on NM_001080408.2) | Missense Mutation (SNP) | VAF 128/439 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs755884628; called by muse, mutect2, varscan2
- SLC26A4 | c.1312C>G p.L438V | Missense Mutation (SNP) | VAF 42/507 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.402); catalogued as COSV55914361; called by muse, mutect2
- ATR | c.6061A>G p.I2021V | Missense Mutation (SNP) | VAF 27/247 reads (11%) | SIFT tolerated (0.9); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CRISP1 | c.54G>A p.M18I | Missense Mutation (SNP) | VAF 54/200 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- EXD3 | c.2464A>G p.R822G | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- IRAG1 | c.463G>T p.E155* | Nonsense Mutation (SNP) | VAF 126/327 reads (39%) | called by muse, mutect2, varscan2
- IZUMO1 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 93/579 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- MYH13 | c.5255C>T p.S1752F | Missense Mutation (SNP) | VAF 64/1202 reads (5%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.797); called by muse, mutect2
- MYO15A | c.10096G>A p.E3366K | Missense Mutation (SNP) | VAF 232/3406 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.221); called by muse, mutect2
- NELFB | c.452T>C p.L151P | Missense Mutation (SNP) | VAF 278/751 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- PCDHB14 | c.2036C>G p.A679G | Missense Mutation (SNP) | VAF 226/610 reads (37%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRAMEF33 | c.1414C>T p.L472F | Missense Mutation (SNP) | VAF 47/300 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- PRKCA | c.1186A>G p.K396E | Missense Mutation (SNP) | VAF 75/773 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- RIMS3 | c.319T>C p.S107P | Missense Mutation (SNP) | VAF 36/499 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TMEM102 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- GGT1 | c.1038C>T p.T346= | Silent (SNP) | VAF 61/566 reads (11%) | called by muse, varscan2
- GGT1 | c.1197C>G p.T399= | Silent (SNP) | VAF 68/596 reads (11%) | called by muse, varscan2
- ITPRID1 | c.1047T>G p.P349= | Silent (SNP) | VAF 109/1141 reads (10%) | called by muse, mutect2
- KATNAL2 | c.1143G>A p.L381= (on ENST00000356157 / NM_001353899.1; = p.L309= on NM_031303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/530 reads (5%) | called by muse, mutect2
- MYH1 | c.2394G>A p.G798= | Silent (SNP) | VAF 117/465 reads (25%) | catalogued as rs765492937; called by muse, mutect2, varscan2
- MYO5B | c.2025G>A p.V675= | Silent (SNP) | VAF 29/150 reads (19%) | called by muse, mutect2
- OTOG | c.987C>T p.S329= | Silent (SNP) | VAF 46/467 reads (10%) | catalogued as rs1009931498; called by muse, mutect2, varscan2
- RSL1D1 | c.25C>T p.L9= | Silent (SNP) | VAF 135/306 reads (44%) | called by muse, mutect2, varscan2
- UNC80 | c.7017G>A p.L2339= | Silent (SNP) | VAF 64/812 reads (8%) | called by muse, mutect2
- WDR87 | c.5073C>T p.N1691= | Silent (SNP) | VAF 70/1190 reads (6%) | catalogued as rs1388144961, COSV58204539; called by muse, mutect2
- CSF2RA | c.810+115C>T | Intron (SNP) | VAF 50/178 reads (28%) | catalogued as rs58223116; called by muse, varscan2
- FAM95C | c.559-205G>A | Intron (SNP) | VAF 10/176 reads (6%) | called by muse, mutect2
- TTN | c.10360+2019A>G | Intron (SNP) | VAF 81/410 reads (20%) | called by muse, mutect2, varscan2
